Somatic mutation profile of tumor specimen TCGA-NH-A50U-01A (aliquot TCGA-NH-A50U-01A-33D-A36X-10) from TCGA case TCGA-NH-A50U, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVA; Age at diagnosis: 42.3 years (15,450 days).
Specimen TCGA-NH-A50U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4758bef7-f8cf-4cd5-98cd-eba3644c13bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A50U-10A (Blood Derived Normal), aliquot TCGA-NH-A50U-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54137a35-e173-45dc-b7d9-611928f779fe

The open-access MAF lists 89 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, Nonsense Mutation 5, Splice Region 2, In Frame Ins 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 32/56 reads (57%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- EYA4 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 32/177 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, varscan2
- GRIN2A | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796052550, COSV58048141, COSV58055595; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- RAB7A | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs121909079, CM030708, COSV99413933; ClinVar: uncertain significance / not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 45/54 reads (83%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AK7 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 67/106 reads (63%) | catalogued as rs745377119, COSV99967073; called by muse, mutect2, varscan2
- AP2A2 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100172633; called by muse, mutect2, varscan2
- APOD | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.23); catalogued as rs5954; called by muse, mutect2, varscan2
- ATG12 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99174628; called by muse, mutect2, varscan2
- BACH2 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99998537; called by muse, mutect2, varscan2
- BPIFC | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.909); catalogued as COSV99322006; called by muse, mutect2, varscan2
- CACNA1B | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99495957; called by muse, mutect2, varscan2
- CALN1 | c.248G>A p.R83H (on ENST00000329008 / NM_001017440.3; = p.R125H on NM_031468.4) | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs771972574, COSV100210142, COSV61119556; called by muse, mutect2, varscan2
- CDC42BPA | c.3546_3553del p.A1183* (on ENST00000334218 / NM_001366019.2; = p.A1170* on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/131 reads (37%) | catalogued as COSV62002148; called by mutect2, pindel, varscan2
- CDH23 | c.7987T>A p.F2663I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV99819610; called by muse, mutect2, varscan2
- CLUH | c.1189G>A p.A397T (on ENST00000435359; = p.A435T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748785564, COSV101425669; called by muse, mutect2, varscan2
- CNTN5 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674437; called by muse, mutect2, varscan2
- COL27A1 | c.2710G>A p.G904R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375632196, COSV100621205, COSV61921648; called by muse, mutect2, varscan2
- CPXM1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs543432133, COSV66045594, COSV66046078; called by muse, mutect2
- DENND11 | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV101530697; called by muse, mutect2, varscan2
- DPYS | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs150948846, COSV100679122, COSV60908630; called by muse, mutect2, varscan2
- DSG3 | c.578A>T p.K193I | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99933910; called by muse, mutect2, varscan2
- DUSP2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as rs751919546, COSV56620882; called by muse, mutect2, varscan2
- EIF2AK4 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs570311740, COSV55472964; called by muse, mutect2
- EYA4 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100765411; called by muse, mutect2, varscan2
- FAM184A | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 142/315 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100137534; called by muse, mutect2, varscan2
- FCRL5 | c.208A>C p.T70P | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100708666; called by muse, mutect2, varscan2
- FGD2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769637078, COSV99235966; called by muse, mutect2, varscan2
- FGF8 | c.411G>A p.K137= (on ENST00000344255 / NM_033164.4; = p.K119= on NM_006119.6) | Splice Region (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100199332; called by muse, mutect2, varscan2
- FNDC1 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as COSV51933564; called by muse, mutect2, varscan2
- GAD2 | c.887C>A p.T296K | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs769617908, COSV52157529, COSV99392774; called by muse, mutect2, varscan2
- GPR63 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 49/110 reads (45%) | catalogued as rs955123836, COSV100013091, COSV57740915; called by muse, mutect2, varscan2
- GRM3 | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862256, COSV64477875; called by muse, mutect2, varscan2
- HMGCLL1 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99231664; called by muse, mutect2, varscan2
- HPCAL1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100323842; called by muse, mutect2, varscan2
- KIF1A | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1283675580, COSV100240198; called by muse, mutect2, varscan2
- KIF2B | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214581422, COSV52130895; called by muse, mutect2, varscan2
- KRT2 | c.703A>G p.S235G | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100548362; called by muse, mutect2, varscan2
- LHX6 | c.482C>T p.S161L (on ENST00000373755 / NM_001242334.2; = p.S190L on NM_014368.5) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100493274; called by muse, mutect2, varscan2
- LRRIQ1 | c.4844A>G p.H1615R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV101279772; called by muse, mutect2, varscan2
- MAP7D2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1259584502, COSV65528975; called by muse, mutect2
- MEPCE | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as rs745881376, COSV99439850; called by muse, mutect2, varscan2
- MLLT10 | c.1623A>G p.E541= | Splice Region (SNP) | VAF 48/154 reads (31%) | catalogued as COSV56991047; called by muse, mutect2, varscan2
- MTHFD1 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767011731, COSV53699285; called by muse, mutect2, varscan2
- MYCBP2 | c.7417G>A p.D2473N (on ENST00000357337; = p.D2511N on NM_015057.5) | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1407884426, COSV62010082; called by muse, mutect2, varscan2
- NAV1 | c.4870G>A p.V1624M | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55216326; called by muse, mutect2, varscan2
- NOS2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141690665; called by muse, mutect2, varscan2
- OR5M8 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100510584; called by muse, varscan2
- PDXDC1 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1567718376, COSV100362976; called by muse, mutect2, varscan2
- PEG3 | c.920A>C p.D307A | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV99687901; called by muse, mutect2, varscan2
- POLE | c.6119C>T p.A2040V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs5745021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPHLN1 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99871573; called by muse, mutect2, varscan2
- RASA1 | c.1050-1G>T p.X350_splice | Splice Site (SNP) | VAF 99/152 reads (65%) | catalogued as COSV57203182, COSV99169670; called by muse, mutect2, varscan2
- RNF103 | c.1470G>T p.L490F | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV99410022; called by muse, mutect2, varscan2
- SECISBP2L | c.2371G>A p.V791I (on ENST00000559471 / NM_001193489.2; = p.V746I on NM_014701.4) | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.58); catalogued as rs772356905, COSV55933752, COSV55937384; called by muse, mutect2, varscan2
- SERPINA7 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.693); catalogued as COSV100568242; called by muse, mutect2
- SLITRK6 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs371704272; called by muse, mutect2, varscan2
- SMAD2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 34/43 reads (79%) | catalogued as COSV100053459; called by muse, mutect2, varscan2
- SOS2 | c.3419G>A p.S1140N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99365627; called by muse, mutect2, varscan2
- SP140 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 105/525 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs757998046, COSV100613340; called by muse, varscan2
- TECTA | c.3763C>T p.P1255S | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1177919020, COSV99879093; called by muse, mutect2, varscan2
- TP63 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM093598, COSV99286036, COSV99286970; called by muse, mutect2, varscan2
- TSPAN2 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV101049846, COSV65690192; called by muse, mutect2, varscan2
- TWF2 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100564480; called by muse, mutect2, varscan2
- ZNF18 | c.1489T>C p.C497R | Missense Mutation (SNP) | VAF 115/139 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503055; called by muse, mutect2, varscan2
- ANGPT1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ESRRG | c.170_172dup p.S57_P58insR | In Frame Ins (INS) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- AMBN | c.1215C>T p.S405= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs762671034, COSV100534289; called by muse, mutect2, varscan2
- BSN | c.1860G>A p.P620= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs1369895463, COSV56530389; called by muse, mutect2, varscan2
- CLEC14A | c.525T>C p.F175= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV60561676; called by muse, mutect2, varscan2
- ESRRB | c.117C>T p.S39= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1207603998, COSV99834964; called by muse, mutect2, varscan2
- FBXO17 | c.255C>T p.N85= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV53068845; called by muse, mutect2, varscan2
- FLNC | c.7581C>T p.I2527= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs988685183, COSV57952342; called by muse, mutect2, varscan2
- LENG8 | c.2016C>T p.F672= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100417931; called by muse, mutect2
- MCHR2 | c.39C>T p.A13= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs374330201; called by muse, mutect2, varscan2
- NELL2 | c.1791A>G p.G597= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100419029; called by muse, mutect2
- NKX3-2 | c.561C>T p.S187= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs913414831, COSV101219857; called by muse, mutect2, varscan2
- PARD6G | c.771G>A p.V257= | Silent (SNP) | VAF 37/46 reads (80%) | catalogued as COSV100783358; called by muse, mutect2, varscan2
- PRRC2C | c.3714C>T p.L1238= (on ENST00000367742; = p.L1236= on NM_015172.4) | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as rs1373566973, COSV100144894; called by muse, mutect2, varscan2
- PSME4 | c.4155T>G p.G1385= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV101122359; called by muse, mutect2, varscan2
- RYR1 | c.12381C>T p.F4127= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV62087981; called by muse, mutect2, varscan2
- SIRT6 | c.147C>T p.F49= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as COSV100511212; called by muse, mutect2, varscan2
- SYMPK | c.2205C>T p.F735= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as COSV99841498; called by muse, mutect2, varscan2
- UBR2 | c.90A>G p.Q30= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100868474; called by muse, mutect2, varscan2
- UNC13C | c.4608A>C p.P1536= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as COSV52843102; called by muse, mutect2, varscan2
- USH2A | c.6967C>A p.R2323= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as CM165968, COSV100231332, COSV56376785; called by muse, mutect2, varscan2
- ZBTB46 | c.1116G>A p.A372= | Silent (SNP) | VAF 48/81 reads (59%) | catalogued as rs984437948, COSV99828887; called by muse, mutect2, varscan2
- ZNF18 | c.1488C>T p.I496= | Silent (SNP) | VAF 113/137 reads (82%) | catalogued as COSV100503058; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156909 C>T | 3'Flank (SNP) | VAF 22/65 reads (34%) | catalogued as rs375813573; called by muse, mutect2, varscan2
